Somatic mutation profile of tumor specimen BA2455D (aliquot aq-BA2455D) from BEATAML1.0 case 2373, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.9 years (26,620 days).
Specimen BA2455D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8118475-62d9-480b-a420-3a4603f4cd8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2149D (Solid Tissue Normal), aliquot aq-BA2149D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3b32716-2115-41a3-80de-1ecd01dd8597

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.863_864insTAGG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by pindel, varscan2
- ARID5B | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PTPRB | c.5258C>T p.P1753L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCUBE3 | c.2200C>A p.H734N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2
- SPRED2 | c.1010T>A p.I337N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMC3 | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHFR | c.594A>G p.A198= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs965751134; called by muse, mutect2
- PLXNB1 | c.2550C>T p.P850= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs774347842; called by muse, mutect2, varscan2
- CAPN11 | c.1746+14dup | Intron (INS) | VAF 46/122 reads (38%) | called by mutect2, pindel, varscan2
- GPR137 | c.1032-88C>T | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, varscan2
